CCDI case PBBMZW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/810b28fc-27ba-4828-a966-75502b2f91d1

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 22.3 years (8,140 days).

Biospecimens (3 samples)
- Sample 0DDX65: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DDX8R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DEK0Y: Tissue type: Tumor; Specimen type: Solid Tissue.
